Somatic mutation profile of tumor specimen MP2PRT-PAVWAG-TMP1-A (aliquot MP2PRT-PAVWAG-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVWAG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.3 years (1,945 days).
Specimen MP2PRT-PAVWAG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8553ceca-1236-48a0-af0f-b8628fa2a456.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVWAG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVWAG-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97250bf5-c9d7-480a-bd51-f8cf47da3b6b

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL031777.2 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 187/326 reads (57%) | SIFT deleterious, low confidence (0.05); catalogued as COSV100587264, COSV61912013, COSV61912148; called by muse, mutect2, varscan2
- ATP13A5 | c.1377G>C p.K459N | Missense Mutation (SNP) | VAF 136/328 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.183); catalogued as rs769439505; called by muse, mutect2, varscan2
- EPHA5 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 136/350 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs770587480, COSV56633488; called by muse, mutect2, varscan2
- SRGAP3 | c.1711C>T p.R571* | Nonsense Mutation (SNP) | VAF 103/278 reads (37%) | catalogued as COSV64540670; called by muse, mutect2, varscan2
- AKAP4 | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 150/172 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CHD8 | c.3004G>A p.E1002K (on ENST00000646647 / NM_001170629.2; = p.E723K on NM_020920.4) | Missense Mutation (SNP) | VAF 103/342 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- FAT4 | c.5270C>T p.S1757F | Missense Mutation (SNP) | VAF 65/237 reads (27%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714674 ACACTGTGTCTCTCGCACAGTAAT>CTTCC | Missense Mutation (DEL) | VAF 19/57 reads (33%) | called by pindel, varscan2*
- SRPK2 | c.2027C>T p.S676L | Missense Mutation (SNP) | VAF 23/309 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); called by muse, mutect2
- CFL1 | c.192C>T p.V64= | Silent (SNP) | VAF 114/303 reads (38%) | catalogued as rs11550148; called by muse, mutect2, varscan2
- METAP1 | c.891C>T p.H297= | Silent (SNP) | VAF 107/272 reads (39%) | called by muse, mutect2, varscan2
- NISCH | c.4215C>T p.Y1405= | Silent (SNP) | VAF 40/551 reads (7%) | called by muse, mutect2
- OR13C2 | c.129T>C p.G43= | Silent (SNP) | VAF 83/260 reads (32%) | called by muse, mutect2, varscan2
- SIGLEC7 | c.1323C>T p.S441= | Silent (SNP) | VAF 87/290 reads (30%) | called by muse, mutect2, varscan2
